Somatic mutation profile of tumor specimen C3N-01515-01 (aliquot CPT0079790009) from CPTAC case C3N-01515, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen C3N-01515-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cd42fa5-dcdd-46f3-8169-0700f03831c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01515-31 (Blood Derived Normal), aliquot CPT0080730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1f81fb5-a1be-4039-9a60-b43cd73fbcaf

The open-access MAF lists 111 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 26, Intron 8, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 3, Splice Region 2, 5'Flank 2, 5'UTR 2, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 75/386 reads (19%) | catalogued as rs886039558, CM920998, COSV65953893; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, mutect2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- C10orf71 | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs762091617; called by muse, mutect2, varscan2
- CFAP54 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs999647017; called by muse, mutect2, varscan2
- FAM133A | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59075717, COSV59075955; called by muse, mutect2, varscan2
- FER1L4 | n.3002C>T | Splice Region (SNP) | VAF 26/108 reads (24%) | catalogued as rs1013897942; called by muse, mutect2
- FLII | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200522954, COSV58945525; called by muse, mutect2, varscan2
- FRAS1 | c.4807C>T p.R1603W | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.443); catalogued as rs961911715, COSV53655438, COSV99348786; ClinVar: likely benign; called by muse, mutect2, varscan2
- FSTL4 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761186958, COSV54777832; called by muse, mutect2, varscan2
- G6PD | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM123589, COSV63703602; called by muse, mutect2, varscan2
- GPR26 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV52933099; called by muse, mutect2, varscan2
- GRIN2A | c.4018A>T p.K1340* | Nonsense Mutation (SNP) | VAF 50/305 reads (16%) | catalogued as rs779641000, COSV100411559; called by muse, mutect2, varscan2
- KIF26A | c.4085del p.P1362Rfs*24 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as rs776136395; called by mutect2, pindel, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 48/193 reads (25%) | catalogued as rs375319628; called by muse, mutect2, varscan2
- LY9 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs201014786; called by muse, mutect2, varscan2
- LYPD2 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766170996, COSV63649125; called by muse, mutect2, varscan2
- PCDHGA7 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs974144646, COSV53919493; called by muse, mutect2, varscan2
- PCDHGB2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as rs1214770155; called by muse, mutect2, varscan2
- PEAK1 | c.3509A>G p.K1170R | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs773112275; called by muse, mutect2, varscan2
- PIEZO2 | c.6988G>A p.V2330I | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs756549202, COSV53286661; called by muse, mutect2, varscan2
- PLEKHG4 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 131/698 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as rs753603363, COSV100846408, COSV64614003; called by muse, mutect2, varscan2
- PTCH1 | c.3204C>A p.F1068L | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs762419846, COSV59469335; called by muse, mutect2, varscan2
- TAS2R40 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs374345239; called by muse, mutect2, varscan2
- TMEM108 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749873619, COSV58873724; called by muse, mutect2, varscan2
- TOE1 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV59155034; called by muse, mutect2, varscan2
- UBN2 | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943757; called by muse, mutect2, varscan2
- WDR81 | c.3693G>T p.W1231C (on ENST00000409644 / NM_001163809.2; = p.W180C on NM_152348.4) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58485848; called by muse, mutect2, varscan2
- ZNF566 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101091471; called by muse, mutect2, varscan2
- ZSCAN10 | c.1048G>A p.A350T (on ENST00000252463; = p.A405T on NM_032805.3) | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs374247812, COSV99374354; called by muse, mutect2, varscan2
- ADPRM | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ASZ1 | c.1344_1346del p.S448del | In Frame Del (DEL) | VAF 19/107 reads (18%) | called by pindel, varscan2
- CAMTA1 | c.1700G>T p.S567I | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- CBL | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- CCDC175 | c.1939T>C p.Y647H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL15A1 | c.2761G>A p.G921S | Missense Mutation (SNP) | VAF 69/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL7 | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 72/442 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- DST | c.5830del p.A1944Lfs*51 | Frame Shift Del (DEL) | VAF 44/279 reads (16%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- FAM149A | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- FAM71F1 | c.853+2T>C p.X285_splice | Splice Site (SNP) | VAF 29/208 reads (14%) | called by muse, mutect2, varscan2
- FKBP1C | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FMNL3 | c.2650C>T p.L884F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FRK | c.1267del p.L423Ffs*15 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
- GPR139 | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, varscan2
- GRM3 | c.712A>C p.N238H | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KLHDC2 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LGI2 | c.71T>G p.I24R | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, varscan2
- LRRC4C | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MON1A | c.1025G>C p.S342T | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTUS1 | c.1767T>G p.H589Q | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MXRA5 | c.4297C>T p.H1433Y | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NDUFB2 | c.264del p.P89Lfs*9 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- NTN4 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- NUDC | c.97_99del p.F33del | In Frame Del (DEL) | VAF 86/556 reads (15%) | called by pindel, varscan2
- OR1J4 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- OR52A5 | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OXGR1 | c.958A>T p.K320* | Nonsense Mutation (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- PPP1R17 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTEN | c.155_157del p.D52del | In Frame Del (DEL) | VAF 38/108 reads (35%) | called by pindel, varscan2
- PTPN5 | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PZP | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REV3L | c.4975A>G p.S1659G | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF17 | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SELE | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 40/250 reads (16%) | called by muse, mutect2, varscan2
- SETX | c.5762C>A p.T1921N | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STK10 | c.2529C>T p.F843= | Splice Region (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.369T>A p.F123L | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TRO | c.4181C>T p.A1394V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TRPS1 | c.1449dup p.N484Efs*2 (on ENST00000220888 / NM_001330599.2; = p.N497Efs*2 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 95/605 reads (16%) | called by mutect2, pindel, varscan2
- TTC6 | c.317A>G p.N106S (on ENST00000267368; = p.N1375S on NM_001310135.3) | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- WDR81 | c.5590C>T p.H1864Y (on ENST00000409644 / NM_001163809.2; = p.H813Y on NM_152348.4) | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, varscan2
- ADGRF5 | c.2799T>C p.T933= | Silent (SNP) | VAF 52/309 reads (17%) | called by muse, mutect2, varscan2
- BBS12 | c.606T>A p.P202= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- CABP2 | c.627C>T p.V209= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as rs904697651, COSV53708736; called by muse, mutect2, varscan2
- CCDC172 | c.567G>A p.E189= | Silent (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- CTNNB1 | c.117C>A p.A39= | Silent (SNP) | VAF 116/508 reads (23%) | catalogued as COSV62720964; called by muse, mutect2, varscan2
- EXT1 | c.33C>G p.L11= | Silent (SNP) | VAF 72/366 reads (20%) | called by muse, mutect2, varscan2
- FLG | c.2331G>A p.E777= | Silent (SNP) | VAF 114/562 reads (20%) | catalogued as rs746110595; called by muse, mutect2, varscan2
- FLG | c.885C>A p.S295= | Silent (SNP) | VAF 136/649 reads (21%) | called by muse, mutect2, varscan2
- FRAS1 | c.5724C>T p.D1908= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- GIMAP4 | c.942G>A p.A314= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as rs764010824, COSV55431354; called by muse, mutect2, varscan2
- GNA15 | c.837C>T p.T279= | Silent (SNP) | VAF 27/250 reads (11%) | catalogued as rs780032746, COSV53585784; called by muse, mutect2, varscan2
- ING5 | c.105G>A p.T35= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as rs1438135287, COSV100545884; called by muse, varscan2
- LCE1F | c.87C>T p.C29= | Silent (SNP) | VAF 60/355 reads (17%) | catalogued as rs374063171; called by muse, mutect2, varscan2
- MPO | c.1968C>T p.R656= | Silent (SNP) | VAF 49/273 reads (18%) | catalogued as rs143183763, COSV51858032; called by muse, mutect2, varscan2
- MYO1F | c.51C>T p.S17= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as rs777677983; called by muse, mutect2, varscan2
- OR13C8 | c.777C>T p.Y259= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as rs753314500, COSV58612719, COSV99080311; called by muse, mutect2, varscan2
- OR4C5 | c.93G>A p.T31= | Silent (SNP) | VAF 65/286 reads (23%) | catalogued as rs1408422247; called by muse, mutect2, varscan2
- PI4K2A | c.1116G>A p.A372= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs372605084; called by muse, mutect2, varscan2
- PLEKHG4B | c.2022G>A p.L674= (on ENST00000283426; = p.L1030= on NM_052909.5) | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2
- POM121L12 | c.543G>A p.A181= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as rs1278960186, COSV68692981; called by muse, mutect2, varscan2
- TANGO6 | c.2571C>G p.A857= | Silent (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- TBC1D3B | c.756G>C p.G252= | Silent (SNP) | VAF 97/743 reads (13%) | called by muse, mutect2, varscan2
- TMIGD1 | c.621C>T p.D207= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, varscan2
- TTN | c.21030G>A p.T7010= (on ENST00000591111; = p.T6083= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs775230627; called by muse, mutect2, varscan2
- UBQLN2 | c.231C>T p.A77= | Silent (SNP) | VAF 98/552 reads (18%) | catalogued as rs1303551320, COSV100592723; called by muse, mutect2, varscan2
- ZNF713 | c.1065A>G p.K355= (on ENST00000633730 / NM_001366796.2; = p.K368= on NM_182633.3) | Silent (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- ANO4 | c.-64G>A | 5'UTR (SNP) | VAF 34/197 reads (17%) | catalogued as rs565412977, COSV54598599; called by muse, mutect2, varscan2
- ANXA8L1 | c.207+121A>C | Intron (SNP) | VAF 66/265 reads (25%) | called by muse, mutect2, varscan2
- ELN | c.890-8_890-7del | Intron (DEL) | VAF 81/616 reads (13%) | called by pindel, varscan2
- FAR1 | c.1128-18A>G | Intron (SNP) | VAF 25/87 reads (29%) | catalogued as rs1204090669; called by muse, mutect2, varscan2
- IL16 | c.-188C>T | 5'UTR (SNP) | VAF 36/225 reads (16%) | catalogued as rs200767560; called by muse, mutect2, varscan2
- IRAK1 | c.*873C>T | 3'UTR (SNP) | VAF 53/268 reads (20%) | catalogued as rs1557127256; called by muse, mutect2, varscan2
- JAG1 | c.1721-14A>G | Intron (SNP) | VAF 94/477 reads (20%) | called by muse, mutect2, varscan2
- KIAA1549L | chr11:33542071 G>A | 5'Flank (SNP) | VAF 18/117 reads (15%) | catalogued as rs1273702647; called by muse, mutect2, varscan2
- POLA1 | c.2947-20888C>T | Intron (SNP) | VAF 77/352 reads (22%) | catalogued as rs756349313; called by muse, mutect2, varscan2
- RIMS2 | c.3821+984C>T | Intron (SNP) | VAF 40/158 reads (25%) | called by muse, varscan2
- RNU6-389P | chr7:55685193 G>A | 5'Flank (SNP) | VAF 26/170 reads (15%) | catalogued as rs764015605; called by muse, mutect2, varscan2
- SAMHD1 | c.1410+14C>T | Intron (SNP) | VAF 79/317 reads (25%) | catalogued as rs1172658057; called by muse, mutect2, varscan2
- SPTA1 | c.6788+12G>A | Intron (SNP) | VAF 36/198 reads (18%) | catalogued as rs758150781, COSV63750593; called by muse, mutect2, varscan2
